CPTAC case C3L-00140 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/410b95b4-6d38-4c25-91ad-c09f2c34325b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 70.8 years (25,869 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,802 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,802 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1.9 cm (a second GDC size field records 3 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 8; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 302 days; Disease response: Tumor Free.
- Days to follow up: 742 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,043 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,504 days (4.1 years); Disease response: Tumor Free.
- Days to follow up: 1,802 days (4.9 years); Disease response: Complete Response.
- Days to follow up: 1,802 days (4.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 68 kg; Height: 180 cm; BMI: 20.99; DLCO (% of predicted): 54; FEV1/FVC after bronchodilator (%): 86; FEV1/FVC before bronchodilator (%): 94; FEV1 after bronchodilator (% of reference): 79; FEV1 before bronchodilator (% of reference): 75.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 2.5; Cigarettes per day: 1; Tobacco smoking onset year: 1965; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 57.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00140-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 322 mg.
- Sample C3L-00140-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 373 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00140-22: Section location: Right Upper Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-00140-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 442 mg.
- Sample C3L-00140-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 415 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00140-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
